Somatic mutation profile of tumor specimen TCGA-19-1389-02A (aliquot TCGA-19-1389-02A-21D-2280-08) from TCGA case TCGA-19-1389, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.1 years (18,659 days).
Specimen TCGA-19-1389-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8588571e-3d80-41e1-a712-b2e90b7aa491.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1389-10C (Blood Derived Normal), aliquot TCGA-19-1389-10C-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71fc7244-33c9-4e24-b9f7-cb5a68449298

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 18, Silent 9, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CB | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV56683948; called by muse, mutect2, varscan2
- APH1B | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs748818637, COSV99971395; called by muse, mutect2, varscan2
- BTNL8 | c.800C>T p.A267V (on ENST00000340184 / NM_001040462.3; = p.G310= on NM_024850.2) | Missense Mutation (SNP) | VAF 152/655 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.134); catalogued as rs755335177, COSV99180400; called by muse, mutect2, varscan2
- C12orf29 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs139590799; called by muse, mutect2
- CDH5 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs745990585, COSV58517776; called by muse, mutect2, varscan2
- DNAH3 | c.5512G>A p.E1838K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1420999638, COSV99764133; called by muse, mutect2, varscan2
- E2F7 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as rs776564666; called by muse, mutect2, varscan2
- FILIP1 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV52741789; called by muse, mutect2, varscan2
- GK2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as rs752639242, COSV100725869, COSV62626389; called by muse, mutect2, varscan2
- GPR158 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs371356903; called by muse, mutect2, varscan2
- GRM1 | c.2246G>T p.S749I | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263193; called by muse, mutect2, varscan2
- KNL1 | c.3532G>A p.D1178N (on ENST00000346991 / NM_170589.5; = p.D1152N on NM_144508.5) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.36); catalogued as COSV100705726; called by muse, mutect2, varscan2
- OR4C16 | c.296T>A p.V99D | Missense Mutation (SNP) | VAF 25/373 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs747562115; called by muse, mutect2
- OR6F1 | c.766del p.V256Ffs*15 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | catalogued as COSV57468071; called by mutect2, pindel, varscan2
- PIM1 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100998563, COSV100998679; called by muse, mutect2, varscan2
- PPARGC1A | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs767722215, COSV53532639; called by muse, mutect2, varscan2
- CPSF3 | c.288del p.H97Mfs*64 | Frame Shift Del (DEL) | VAF 19/101 reads (19%) | called by mutect2, pindel, varscan2
- MLKL | c.587T>G p.I196S | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPRYD4 | c.400A>T p.M134L | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TDRD7 | c.2453A>C p.Y818S | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ABCB4 | c.3585C>A p.A1195= (on ENST00000265723 / NM_018849.3; = p.A1188= on NM_000443.4) | Silent (SNP) | VAF 62/299 reads (21%) | called by muse, mutect2, varscan2
- ATP12A | c.1782G>A p.P594= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs1452581735, COSV54513773; called by muse, mutect2, varscan2
- ATP1A4 | c.858G>A p.A286= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as rs369914363; called by muse, mutect2, varscan2
- CLEC18B | c.1287C>T p.N429= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as rs373302916; called by muse, mutect2, varscan2
- CNGA4 | c.699C>T p.G233= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs1484597104, COSV66006711; called by muse, mutect2, varscan2
- IGF2BP1 | c.195A>G p.G65= | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- NR4A2 | c.1338G>C p.L446= | Silent (SNP) | VAF 78/376 reads (21%) | called by muse, mutect2, varscan2
- PTPN22 | c.1023A>G p.Q341= (on ENST00000359785 / NM_001193431.2; = p.Q286= on NM_012411.5) | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100703298; called by muse, mutect2, varscan2
- ZNF280A | c.1521C>T p.S507= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs760808646, COSV100130890; called by muse, mutect2, varscan2
